Somatic mutation profile of tumor specimen TCGA-05-4382-01A (aliquot TCGA-05-4382-01A-01D-1931-08) from TCGA case TCGA-05-4382, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.1 years (24,868 days).
Specimen TCGA-05-4382-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d30c9651-0eee-4446-aa6f-5dbbb1c3cab4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4382-10A (Blood Derived Normal), aliquot TCGA-05-4382-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/879297cc-5afe-48aa-9a38-e8b1c6fe0a32

The open-access MAF lists 1,824 somatic variants for this specimen: 1,413 protein-altering or splice-affecting, 365 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,225, Silent 365, Nonsense Mutation 100, Splice Site 43, Frame Shift Del 22, Intron 19, RNA 13, Splice Region 9, Frame Shift Ins 9, 5'UTR 4, 5'Flank 4, 3'UTR 3.

Variants (750 of 1,824; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.3673C>T p.Q1225* | Nonsense Mutation (SNP) | VAF 15/122 reads (12%) | catalogued as rs1555092430, CM031637, COSV99588105; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BBS10 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 12/133 reads (9%) | catalogued as rs1310735399, COSV99674690; ClinVar: likely pathogenic; called by muse, mutect2
- OFD1 | c.2668C>T p.R890* | Nonsense Mutation (SNP) | VAF 23/169 reads (14%) | catalogued as rs863225212, COSV100366087; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.815T>G p.V272G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876660333, CM942122, COSV52701102, COSV52773741, COSV52787833, COSV53259929; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A1CF | c.1782C>A p.F594L (on ENST00000373993 / NM_138932.2; = p.F586L on NM_014576.4) | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as COSV99255516; called by muse, mutect2, varscan2
- AADACL3 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 53/357 reads (15%) | catalogued as COSV100206610; called by muse, mutect2, varscan2
- AAK1 | c.2599G>T p.D867Y | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV101275901; called by muse, mutect2
- ABCA1 | c.1972G>C p.G658R | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV101036666; called by muse, mutect2, varscan2
- ABCA2 | c.5276A>T p.Q1759L (on ENST00000614293; = p.Q1729L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV99687145; called by muse, mutect2
- ABCA2 | c.4141G>T p.A1381S (on ENST00000614293; = p.A1351S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99687147; called by muse, mutect2
- ABCA4 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as HM070110; called by muse, mutect2
- ABCA9 | c.4497G>T p.L1499= | Splice Region (SNP) | VAF 82/252 reads (33%) | catalogued as COSV100382796; called by muse, mutect2, varscan2
- ABCB5 | c.3274C>A p.Q1092K (on ENST00000404938 / NM_001163941.2; = p.Q647K on NM_178559.6) | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV99327751, COSV99329115; called by muse, mutect2, varscan2
- ABCC12 | c.3080T>A p.L1027Q | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100252321; called by muse, mutect2
- ABCC12 | c.1505T>A p.V502E | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100252322; called by muse, varscan2
- ABCC8 | c.2885G>T p.R962M | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100216827; called by muse, mutect2, varscan2
- ABL2 | c.2224G>T p.G742W (on ENST00000502732 / NM_007314.4; = p.G727W on NM_005158.5) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100772570; called by muse, mutect2, varscan2
- AC008397.2 | c.1190C>A p.A397D | Missense Mutation (SNP) | VAF 76/374 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV53206356, COSV99441367; called by muse, mutect2, varscan2
- ACAD11 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs1347456083, COSV99391730; called by muse, mutect2, varscan2
- ACADM | c.563A>T p.Q188L | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV100273453; called by muse, mutect2, varscan2
- ACE | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.05); catalogued as COSV99326584; called by muse, mutect2
- ACE | c.2813C>G p.P938R | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99326588; called by muse, mutect2
- ACOT12 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as rs1402293491, COSV100296800; called by muse, mutect2, varscan2
- ACOT6 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV101141896; called by muse, mutect2, varscan2
- ACSM1 | c.680G>T p.S227I | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99532673; called by muse, mutect2, varscan2
- ACSM2A | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99525016; called by muse, mutect2, varscan2
- ACSM2B | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 170/565 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100312451, COSV99052177; called by muse, mutect2, varscan2
- ACTG2 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.187); catalogued as COSV100608921; called by muse, mutect2
- ACVR2B | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs926985338, COSV100754184; called by muse, mutect2, varscan2
- ADAM11 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52345801, COSV99567215; called by muse, mutect2, varscan2
- ADAM17 | c.283A>C p.K95Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV100176106; called by muse, mutect2, varscan2
- ADAM18 | c.1900G>A p.G634R | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443274583, COSV99695117, COSV99695907; called by muse, mutect2, varscan2
- ADAM19 | c.211G>C p.A71P | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57429853, COSV99976491; called by muse, mutect2, varscan2
- ADAMTS1 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV99535942; called by muse, mutect2
- ADAMTS12 | c.3140C>A p.A1047E | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.112); catalogued as COSV100710456, COSV61257608, COSV61272417; called by muse, mutect2, varscan2
- ADAMTS18 | c.1925C>A p.P642H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV99271646; called by muse, mutect2, varscan2
- ADAMTS2 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99201132; called by muse, mutect2, varscan2
- ADAMTS3 | c.3316A>T p.I1106F | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV99710483; called by muse, mutect2, varscan2
- ADAMTS7 | c.1840G>C p.G614R | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV101183048; called by muse, mutect2
- ADAMTS9 | c.5414A>G p.Y1805C | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs1434282695, COSV99898965; called by muse, mutect2
- ADAMTS9 | c.3043G>T p.G1015C | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99898966; called by muse, mutect2, varscan2
- ADAT2 | c.123A>T p.E41D | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99395672; called by muse, mutect2, varscan2
- ADCY8 | c.1426C>A p.Q476K | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.213); catalogued as COSV53897782, COSV53912759; called by muse, mutect2, varscan2
- ADCY9 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99569573; called by muse, mutect2
- ADCYAP1R1 | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV100416306; called by muse, mutect2, varscan2
- ADD1 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV99296145; called by muse, mutect2, varscan2
- ADGRA3 | c.1443+1G>T p.X481_splice | Splice Site (SNP) | VAF 19/137 reads (14%) | catalogued as COSV99293054; called by muse, mutect2, varscan2
- ADGRB3 | c.3406G>T p.D1136Y | Missense Mutation (SNP) | VAF 23/311 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53246396; called by muse, mutect2
- ADGRE5 | c.757G>C p.D253H (on ENST00000242786 / NM_078481.4; = p.D160H on NM_001784.5) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.649); catalogued as COSV99662729; called by muse, mutect2, varscan2
- ADGRG1 | c.1886C>G p.S629C | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101113376; called by muse, mutect2
- ADGRG1 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100342176; called by muse, mutect2, varscan2
- ADGRG4 | c.1958A>T p.E653V | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99794773; called by muse, mutect2, varscan2
- ADGRG4 | c.7747C>G p.H2583D | Missense Mutation (SNP) | VAF 262/649 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV99794774; called by muse, mutect2, varscan2
- ADGRL2 | c.2897G>T p.G966V (on ENST00000370717 / NM_001366005.1; = p.G953V on NM_012302.4) | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1164753366, COSV54665457, COSV99587647; called by muse, mutect2, varscan2
- ADGRL3 | c.2533G>T p.V845F (on ENST00000506720 / NM_001322402.2; = p.V777F on NM_015236.6) | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101546923; called by muse, mutect2
- ADRA2B | c.473C>A p.P158Q | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.111); catalogued as rs759607097, COSV101337349, COSV69787367; called by muse, mutect2, varscan2
- AFAP1L1 | c.503C>A p.A168E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV99695693; called by muse, mutect2
- AGBL1 | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101222398; called by muse, mutect2, varscan2
- AGBL1 | c.3251A>T p.H1084L | Missense Mutation (SNP) | VAF 58/357 reads (16%) | PolyPhen benign (0); catalogued as COSV101222399, COSV66878784; called by muse, mutect2, varscan2
- AGMO | c.1041G>T p.L347F | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV100693808; called by muse, mutect2, varscan2
- AGPAT3 | c.1069G>T p.G357* | Nonsense Mutation (SNP) | VAF 54/445 reads (12%) | catalogued as COSV99377245; called by muse, mutect2, varscan2
- AGPS | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99931135; called by muse, mutect2, varscan2
- AHCTF1 | c.1903A>G p.R635G (on ENST00000366508; = p.R609G on NM_015446.5) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.461); catalogued as COSV100403327; called by mutect2, varscan2
- AHSG | c.1104G>T p.*368Yext*70 | Nonstop Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99889901; called by muse, mutect2, varscan2
- AK2 | c.308A>T p.H103L (on ENST00000354858; = p.H145L on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/402 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100709886; called by muse, mutect2, varscan2
- AKAP11 | c.4079G>A p.S1360N | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV50298870; called by muse, mutect2, varscan2
- AKNA | c.1178G>T p.R393M | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV99799891; called by muse, mutect2, varscan2
- AL592490.1 | c.2734T>A p.C912S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs1290050895, COSV101308129; called by muse, mutect2, varscan2
- ALDH16A1 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764960127, COSV99512681; called by muse, mutect2
- ALDH1A2 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); catalogued as COSV99990520; called by muse, mutect2
- ALDH1L2 | c.118C>A p.H40N | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99310801; called by muse, mutect2, varscan2
- ALG11 | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101584261; called by muse, mutect2, varscan2
- ALG3 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99890915; called by muse, mutect2, varscan2
- ALMS1 | c.10558G>T p.D3520Y | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CD156290, COSV100041589; called by muse, mutect2, varscan2
- ALMS1 | c.11047G>C p.E3683Q | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs759688621, COSV100041591; called by muse, mutect2, varscan2
- ALPI | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV99785746; called by muse, mutect2, varscan2
- ALPK1 | c.3184G>T p.G1062W | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99453387; called by muse, mutect2
- AMER3 | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 43/218 reads (20%) | catalogued as COSV100366172, COSV58465910; called by muse, mutect2, varscan2
- AMMECR1 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99466440; called by muse, mutect2, varscan2
- AMPH | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV100341349; called by muse, mutect2, varscan2
- AMY2B | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 30/587 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV100796225; called by muse, mutect2
- ANK2 | c.8660C>T p.P2887L | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as COSV100000360; called by muse, mutect2, varscan2
- ANK2 | c.9776C>A p.S3259Y | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV100000362; called by muse, mutect2, varscan2
- ANKAR | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99853996; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3994G>T p.A1332S | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51850391, COSV99782455; called by muse, mutect2, varscan2
- ANKRD17 | c.2262G>T p.M754I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as COSV100428757; called by muse, mutect2, varscan2
- ANKRD27 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs1306229833, COSV100042633; called by muse, mutect2, varscan2
- ANKRD30A | c.3454C>A p.L1152M (on ENST00000611781; = p.L1096M on NM_052997.2) | Missense Mutation (SNP) | VAF 51/424 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.18); catalogued as COSV100653103; called by muse, mutect2, varscan2
- ANO3 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 75/394 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as rs150999282; called by muse, mutect2, varscan2
- ANO3 | c.812C>G p.P271R | Missense Mutation (SNP) | VAF 19/247 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99881410; called by muse, mutect2
- ANPEP | c.1070G>A p.W357* | Nonsense Mutation (SNP) | VAF 21/147 reads (14%) | catalogued as COSV100262776; called by muse, mutect2, varscan2
- ANXA3 | c.744G>T p.R248S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99363605; called by mutect2, varscan2
- AOC2 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 62/178 reads (35%) | catalogued as COSV99513541; called by muse, mutect2, varscan2
- AP1M1 | c.816+1G>T p.X272_splice | Splice Site (SNP) | VAF 65/509 reads (13%) | catalogued as COSV99358261; called by muse, mutect2, varscan2
- APC | c.4684G>A p.D1562N | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); catalogued as COSV57359708; called by muse, mutect2
- APOB | c.7883C>T p.S2628L | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51950740, COSV99264355; called by muse, mutect2, varscan2
- APOB | c.5652C>A p.N1884K | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs766106302, COSV99264358; called by muse, mutect2, varscan2
- APOB | c.4442T>A p.V1481D | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99264363; called by muse, mutect2, varscan2
- ARAP3 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 39/539 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99499439; called by muse, mutect2
- ARHGAP15 | c.211G>T p.V71F | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99709225; called by muse, mutect2, varscan2
- ARHGAP21 | c.101C>A p.T34N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.697); catalogued as COSV100903526; called by muse, mutect2, varscan2
- ARHGAP26 | c.508G>C p.V170L | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.139); catalogued as COSV99189752; called by muse, mutect2
- ARHGAP32 | c.5395G>T p.G1799W (on ENST00000310343 / NM_001378025.1; = p.G1450W on NM_014715.4) | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100087225; called by muse, mutect2, varscan2
- ARHGAP36 | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99357389; called by muse, mutect2, varscan2
- ARHGAP44 | c.680G>T p.R227M | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99310313; called by muse, mutect2, varscan2
- ARHGEF3 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 87/343 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99575053; called by muse, mutect2, varscan2
- ARID1A | c.5278G>T p.E1760* | Nonsense Mutation (SNP) | VAF 36/178 reads (20%) | catalogued as COSV61386958, COSV99055439; called by muse, mutect2, varscan2
- ARL2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs758628032, COSV55861855; called by mutect2, varscan2
- ARPP21 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99491371; called by muse, mutect2, varscan2
- ARSL | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV101140437; called by muse, mutect2, varscan2
- ASB12 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as COSV100744630; called by muse, mutect2, varscan2
- ASB5 | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV99641400; called by muse, mutect2, varscan2
- ASCL3 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV100366851; called by muse, mutect2, varscan2
- ASIC2 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99859562; called by muse, mutect2, varscan2
- ASIC4 | c.1078C>A p.R360S (on ENST00000347842 / NM_182847.3; = p.R379S on NM_018674.6) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV61733724, COSV99704756; called by muse, mutect2
- ASIC5 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as rs1168515854, COSV73332699; called by muse, mutect2
- ASL | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV100508839; called by muse, mutect2, varscan2
- ASNS | c.613C>G p.H205D | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV99446068; called by muse, mutect2
- ASPM | c.3077A>T p.E1026V | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99659818; called by muse, mutect2, varscan2
- ASS1 | c.431C>G p.P144R | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1414969, COSV100752560, COSV100752593; called by muse, mutect2, varscan2
- ASTN1 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV56064465, COSV99920839; called by muse, mutect2, varscan2
- ASTN1 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.99); catalogued as COSV56062351; called by muse, mutect2, varscan2
- ASTN2 | c.1503C>A p.Y501* (on ENST00000313400 / NM_001365069.1; = p.Y450* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 17/118 reads (14%) | catalogued as COSV100525511; called by muse, mutect2, varscan2
- ASXL1 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.093); catalogued as COSV100038149; called by muse, mutect2, varscan2
- ASXL3 | c.1131C>A p.N377K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99323907; called by muse, mutect2
- ATF2 | c.103-2A>T p.X35_splice | Splice Site (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99908485; called by muse, mutect2, varscan2
- ATG2B | c.3637G>C p.E1213Q | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); catalogued as rs767189921, COSV99951978; called by mutect2, varscan2
- ATP10A | c.2782G>T p.D928Y | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV100790995; called by muse, mutect2, varscan2
- ATP10D | c.2974G>T p.G992W | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99905325; called by muse, mutect2
- ATP12A | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 81/524 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99516935, COSV99517190; called by muse, mutect2, varscan2
- ATP2B2 | c.2345C>T p.P782L (on ENST00000352432; = p.P748L on NM_001683.5) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100659833; called by muse, mutect2, varscan2
- ATP6V1C2 | c.522C>A p.F174L | Missense Mutation (SNP) | VAF 51/329 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.524); catalogued as COSV55360831, COSV99695610; called by muse, mutect2, varscan2
- AVPR1A | c.752C>A p.T251K | Missense Mutation (SNP) | VAF 50/429 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100146795, COSV54546135; called by muse, mutect2, varscan2
- AXDND1 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100858282; called by muse, mutect2, varscan2
- B3GLCT | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs1566102742, COSV100587196; called by muse, mutect2, varscan2
- BARD1 | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53611329; called by muse, mutect2
- BBS5 | c.776C>G p.A259G | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.341); catalogued as COSV99751696; called by muse, mutect2, varscan2
- BCAN | c.1858C>A p.P620T | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV100227934; called by muse, mutect2, varscan2
- BCL6B | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 58/238 reads (24%) | catalogued as COSV99546490; called by muse, mutect2, varscan2
- BIRC6 | c.2454G>T p.R818S | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.037); catalogued as COSV101427991; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2599G>T p.G867W | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV100863656, COSV63245362; called by muse, mutect2, varscan2
- BLID | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 68/373 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV101601708, COSV101601726; called by muse, mutect2, varscan2
- BMP4 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV99816819; called by muse, mutect2, varscan2
- BMP6 | c.406A>T p.M136L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); catalogued as COSV99306501; called by muse, mutect2
- BMPER | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV99779171; called by muse, mutect2, varscan2
- BMPER | c.1452G>T p.M484I | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV99779172; called by muse, mutect2, varscan2
- BMPER | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV99779174; called by muse, mutect2, varscan2
- BMPR1B | c.657G>T p.W219C | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM145509, COSV99215543; called by muse, mutect2, varscan2
- BMS1 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 14/247 reads (6%) | catalogued as COSV100996587; called by muse, mutect2
- BNC1 | c.2252C>A p.T751K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100596992; called by muse, mutect2, varscan2
- BOC | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 43/413 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as COSV99848347; called by muse, varscan2
- BOD1L1 | c.5348A>G p.D1783G | Missense Mutation (SNP) | VAF 46/600 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99238779; called by muse, mutect2
- BOD1L1 | c.5152G>T p.G1718C | Missense Mutation (SNP) | VAF 52/267 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV99238780; called by muse, mutect2, varscan2
- BOD1L1 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765828574, COSV99238783; called by muse, mutect2, varscan2
- BPTF | c.6959A>T p.Q2320L | Missense Mutation (SNP) | VAF 128/357 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100074320, COSV100074369; called by muse, mutect2, varscan2
- BRAF | c.1959G>T p.L653F (on ENST00000288602 / NM_001374244.1; = p.L613F on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV99954692; called by muse, mutect2
- BRCA2 | c.5311G>T p.G1771C | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV101204011; called by muse, mutect2
- BRD2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV100875591; called by muse, mutect2, varscan2
- BRINP2 | c.1118A>T p.Q373L | Missense Mutation (SNP) | VAF 41/587 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV100837916; called by muse, mutect2
- BRIP1 | c.2258-2A>T p.X753_splice | Splice Site (SNP) | VAF 47/160 reads (29%) | catalogued as COSV99369626; called by muse, mutect2, varscan2
- BSND | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100987613; called by muse, mutect2, varscan2
- BTAF1 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV99795067; called by muse, mutect2, varscan2
- BTK | c.1090C>A p.H364N | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM056544, COSV100437421; called by muse, mutect2, varscan2
- BTN2A2 | c.454A>T p.K152* | Nonsense Mutation (SNP) | VAF 19/114 reads (17%) | catalogued as COSV100760267; called by muse, mutect2, varscan2
- BTN2A2 | c.455A>T p.K152M | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV100760278; called by muse, mutect2, varscan2
- C10orf71 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100109861; called by muse, mutect2, varscan2
- C12orf71 | c.734C>A p.A245E | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.801); catalogued as rs1171694904, COSV101460509; called by muse, mutect2, varscan2
- C1orf174 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.838); catalogued as COSV100851732; called by muse, mutect2
- C1orf94 | c.1319G>T p.G440V (on ENST00000488417 / NM_001134734.2; = p.G250V on NM_032884.5) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100974776; called by muse, mutect2
- C22orf42 | c.654+1G>T p.X218_splice | Splice Site (SNP) | VAF 35/232 reads (15%) | catalogued as COSV101173293; called by muse, mutect2, varscan2
- C2CD3 | c.2547G>C p.W849C | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100486347; called by muse, mutect2, varscan2
- C6orf58 | c.210G>C p.Q70H | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.93); catalogued as COSV100314754; called by muse, mutect2, varscan2
- C7 | c.2185G>T p.A729S | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100495563; called by muse, mutect2
- C8A | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100776463; called by muse, mutect2, varscan2
- C8B | c.1037C>A p.T346K | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.315); catalogued as COSV100980720; called by muse, mutect2, varscan2
- CABP5 | c.285del p.K96Nfs*9 | Frame Shift Del (DEL) | VAF 43/200 reads (22%) | catalogued as COSV99506559; called by mutect2, pindel, varscan2
- CACNA1B | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.428); catalogued as COSV99495902; called by muse, mutect2, varscan2
- CACNG3 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs1159817893, COSV99135601; called by muse, mutect2, varscan2
- CAD | c.5354G>A p.R1785H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750293336, COSV53032357; called by mutect2, varscan2
- CADPS | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 20/135 reads (15%) | catalogued as COSV99336658; called by muse, mutect2, varscan2
- CALCR | c.872C>A p.T291N (on ENST00000649521 / NM_001164737.2; = p.T275N on NM_001742.4) | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV100810439; called by muse, mutect2, varscan2
- CAPZA3 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as COSV56851099, COSV99856026; called by muse, mutect2, varscan2
- CASP4 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV101274122; called by muse, mutect2, varscan2
- CASP9 | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1389025289, COSV100423663, COSV61602482; called by muse, mutect2, varscan2
- CATSPER1 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100375729; called by muse, mutect2, varscan2
- CBX8 | c.850G>T p.V284L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs781221605, COSV99485792; called by muse, mutect2
- CCDC150 | c.1330G>C p.V444L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99776628; called by muse, mutect2, varscan2
- CCDC153 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100501242; called by muse, mutect2, varscan2
- CCDC178 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1314108944, COSV55764637; called by muse, mutect2, varscan2
- CCDC178 | c.421A>T p.T141S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV100283923; called by muse, mutect2, varscan2
- CCDC18 | c.2229G>C p.L743F (on ENST00000343253 / NM_001306076.1; = p.L744F on NM_206886.4) | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100159338; called by muse, mutect2, varscan2
- CCDC180 | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 36/355 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100826614; called by muse, mutect2
- CCDC183 | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100565950; called by muse, mutect2
- CCDC30 | c.2026A>T p.K676* (on ENST00000340612; = p.K633* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as COSV100501170; called by muse, mutect2
- CCKBR | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs201374522, COSV100582807; called by muse, mutect2, varscan2
- CCL3L3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 103/383 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs1225681584; called by muse, mutect2, varscan2
- CD109 | c.3631G>T p.G1211W | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99752953; called by muse, mutect2
- CD163 | c.1008G>C p.Q336H | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs1047387935, COSV100775740; called by muse, mutect2, varscan2
- CD1C | c.839G>T p.C280F | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100939366; called by muse, mutect2, varscan2
- CD200R1 | c.752C>A p.T251N (on ENST00000471858 / NM_170780.3; = p.T274N on NM_138806.4) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.048); catalogued as COSV99866901; called by muse, mutect2
- CD5 | c.394T>A p.C132S | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100759767; called by muse, mutect2, varscan2
- CD5L | c.773A>T p.E258V | Missense Mutation (SNP) | VAF 44/350 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100941016; called by muse, mutect2, varscan2
- CD8B | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV100514408; called by muse, varscan2
- CDC27 | c.2095G>T p.D699Y | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99294200, COSV99295677; called by muse, mutect2, varscan2
- CDCP2 | c.263T>A p.L88Q | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100313372; called by muse, mutect2
- CDH10 | c.1731C>G p.S577R | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050534, COSV52571583; called by muse, mutect2, varscan2
- CDH11 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as rs868653167, COSV99217570, COSV99218575; called by muse, mutect2
- CDH12 | c.1409C>A p.T470N | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV101201858; called by muse, mutect2, varscan2
- CDH12 | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101201859; called by muse, mutect2, varscan2
- CDH15 | c.269A>T p.E90V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99228143; called by muse, mutect2
- CDH2 | c.2589T>A p.S863R | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99296134; called by muse, mutect2, varscan2
- CDH20 | c.1298C>A p.P433H | Missense Mutation (SNP) | VAF 29/303 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99404675; called by muse, mutect2, varscan2
- CDH8 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54851718, COSV54864046; called by muse, mutect2, varscan2
- CDH9 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV99142261; called by muse, mutect2, varscan2
- CDKL2 | c.407A>T p.Q136L | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100276789; called by muse, mutect2, varscan2
- CEACAM5 | c.1230T>G p.N410K | Missense Mutation (SNP) | VAF 59/370 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as COSV99703787; called by muse, mutect2, varscan2
- CEBPE | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.497); catalogued as COSV99247397; called by muse, mutect2, varscan2
- CELA3B | c.488G>C p.G163A | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100448630; called by muse, mutect2
- CENPE | c.5873A>C p.Q1958P | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99477302; called by muse, mutect2, varscan2
- CENPI | c.2218C>T p.H740Y | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs757961032, COSV54506187; called by muse, mutect2, varscan2
- CEP120 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV100070934; called by muse, mutect2, varscan2
- CEP131 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1009538672, COSV99487960; called by muse, mutect2, varscan2
- CEP135 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99954226; called by muse, mutect2, varscan2
- CEP164 | c.1943G>T p.R648M | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV99632750; called by muse, mutect2
- CEP250 | c.6332T>A p.L2111Q | Missense Mutation (SNP) | VAF 80/313 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV100698805; called by muse, mutect2, varscan2
- CFAP20 | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.022); catalogued as COSV99343418; called by muse, mutect2, varscan2
- CFAP47 | c.5317A>T p.K1773* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100545060; called by muse, mutect2, varscan2
- CFAP58 | c.221A>T p.N74I | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100458807; called by muse, mutect2, varscan2
- CFAP65 | c.4227G>A p.M1409I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100444802; called by muse, mutect2, varscan2
- CFHR5 | c.1559A>G p.Q520R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV99888208; called by muse, varscan2
- CHAF1A | c.2633G>T p.C878F | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as COSV100010958; called by muse, mutect2, varscan2
- CHD4 | c.721G>T p.V241L | Missense Mutation (SNP) | VAF 43/398 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.927); catalogued as COSV100537567; called by muse, mutect2, varscan2
- CHD9 | c.5645G>T p.S1882I | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99528859; called by muse, mutect2
- CHRFAM7A | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV100241545; called by muse, mutect2
- CHST1 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100346085, COSV100346163; called by muse, mutect2, varscan2
- CHST12 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.623); catalogued as rs775707171, COSV51674095; called by muse, mutect2, varscan2
- CILP2 | c.2590G>T p.A864S | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99364441; called by muse, mutect2, varscan2
- CILP2 | c.3452G>A p.R1151Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs777741669, COSV99364444; called by muse, mutect2
- CIT | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 61/533 reads (11%) | catalogued as COSV99948845; called by muse, mutect2, varscan2
- CKAP2 | c.147G>T p.M49I | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99318140; called by muse, mutect2, varscan2
- CLDN11 | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 59/571 reads (10%) | catalogued as COSV99290949; called by muse, mutect2, varscan2
- CLDN17 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as COSV99729059; called by muse, mutect2
- CLEC1A | c.544-2A>T p.X182_splice | Splice Site (SNP) | VAF 26/182 reads (14%) | catalogued as COSV100191236, COSV59531227; called by muse, varscan2
- CLINT1 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99753616; called by muse, mutect2, varscan2
- CLIP3 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs1346025472, COSV62112083; called by muse, mutect2, varscan2
- CLSTN2 | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV101515592; called by muse, mutect2, varscan2
- CLYBL | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1472421573, COSV100184746, COSV59217305; called by muse, mutect2, varscan2
- CNGA3 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99736298; called by muse, mutect2, varscan2
- CNOT1 | c.5011G>T p.D1671Y | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as COSV99799550; called by muse, mutect2, varscan2
- CNST | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as rs1156927161, COSV100830022; called by muse, mutect2
- CNTN1 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100751109; called by muse, mutect2, varscan2
- CNTNAP2 | c.469del p.R157Afs*5 | Frame Shift Del (DEL) | VAF 41/266 reads (15%) | catalogued as COSV62163155; called by mutect2, pindel, varscan2
- CNTNAP5 | c.2214C>A p.D738E | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70473994, COSV70519333; called by muse, mutect2
- COL11A1 | c.2486G>T p.G829V | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100615516; called by muse, mutect2, varscan2
- COL12A1 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.65); catalogued as COSV100485572; called by muse, mutect2
- COL14A1 | c.2711C>G p.A904G | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.192); catalogued as COSV99918425; called by muse, mutect2, varscan2
- COL14A1 | c.4777G>A p.G1593R | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52847910, COSV99918427; called by muse, mutect2
- COL1A2 | c.3794C>A p.S1265Y | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99798941; called by muse, mutect2, varscan2
- COL20A1 | c.1907C>G p.S636C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100490098; called by muse, mutect2, varscan2
- COL22A1 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs758458741, COSV100277029; called by muse, mutect2, varscan2
- COL27A1 | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 35/417 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV100620807; called by muse, mutect2
- COL28A1 | c.2503G>T p.A835S | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV101258408; called by muse, mutect2, varscan2
- COL4A2 | c.2096-1G>T p.X699_splice | Splice Site (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100847278; called by muse, mutect2
- COL5A1 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as COSV100879662; called by muse, mutect2
- COL5A1 | c.2287-1G>A p.X763_splice | Splice Site (SNP) | VAF 37/229 reads (16%) | catalogued as COSV100879663; called by muse, mutect2, varscan2
- COL5A1 | c.4132G>T p.G1378C | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879664; called by muse, mutect2
- COL5A1 | c.4133G>T p.G1378V | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100879665; called by muse, mutect2
- COL6A2 | c.655A>T p.M219L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100153133; called by muse, mutect2, varscan2
- COL6A3 | c.8191C>A p.P2731T | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV55092262; called by muse, mutect2, varscan2
- COL6A3 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 26/256 reads (10%) | catalogued as COSV99796671; called by muse, mutect2
- COL9A1 | c.2099G>A p.G700D | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100294264; called by muse, mutect2, varscan2
- COLEC12 | c.1588G>T p.G530C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV68368926; called by muse, mutect2
- COPB1 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99999354; called by muse, mutect2, varscan2
- CORIN | c.1516C>A p.L506I | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56690781, COSV56696958; called by muse, mutect2, varscan2
- CPS1 | c.1516C>A p.L506M | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99242459; called by muse, mutect2, varscan2
- CPTP | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs770647006, COSV100028092; called by mutect2, varscan2
- CR1 | c.4760C>T p.S1587F | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); catalogued as COSV100887439; called by muse, mutect2
- CRACD | c.2975G>T p.R992L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99948847, COSV99949774; called by muse, mutect2
- CRACDL | c.2507G>T p.G836V | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369616356; called by muse, mutect2, varscan2
- CRB1 | c.2129-1G>A p.X710_splice | Splice Site (SNP) | VAF 11/90 reads (12%) | catalogued as COSV66329889, COSV66331406; called by muse, mutect2, varscan2
- CRHBP | c.791G>T p.C264F | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99169456; called by muse, mutect2, varscan2
- CROCC | c.825G>T p.E275D | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.585); catalogued as COSV100978106; called by muse, mutect2, varscan2
- CROCC | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.09); catalogued as COSV100978107; called by muse, mutect2, varscan2
- CRYGA | c.37del p.Q13Rfs*26 | Frame Shift Del (DEL) | VAF 22/220 reads (10%) | catalogued as COSV58015934; called by mutect2, pindel, varscan2
- CSMD3 | c.8624G>T p.C2875F (on ENST00000297405 / NM_001363185.1; = p.C2706F on NM_052900.3) | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99828268; called by muse, mutect2
- CSMD3 | c.8529T>A p.C2843* (on ENST00000297405 / NM_001363185.1; = p.C2674* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as COSV99828270; called by muse, mutect2, varscan2
- CSMD3 | c.8179C>A p.P2727T | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as rs1238418857, COSV52133300, COSV52225331; called by muse, mutect2
- CSMD3 | c.7517A>G p.E2506G (on ENST00000297405 / NM_001363185.1; = p.E2402G on NM_052900.3) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99828272; called by muse, mutect2
- CSMD3 | c.1520C>A p.T507N (on ENST00000297405 / NM_001363185.1; = p.T403N on NM_052900.3) | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.392); catalogued as COSV52159060, COSV99828275; called by muse, mutect2
- CSN1S1 | c.470A>T p.Q157L | Missense Mutation (SNP) | VAF 63/487 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV99886577; called by muse, mutect2, varscan2
- CSRNP3 | c.1605G>C p.L535F | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.986); catalogued as COSV100085327; called by muse, mutect2
- CWC22 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.152); catalogued as COSV99844081; called by muse, mutect2
- CYP7A1 | c.1333C>A p.P445T | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100052228; called by muse, mutect2
- D2HGDH | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 28/157 reads (18%) | catalogued as COSV100344252, COSV58321232; called by muse, mutect2, varscan2
- DACH1 | c.2099C>T p.T700M (on ENST00000619232 / NM_001366712.1; = p.T446M on NM_004392.6) | Missense Mutation (SNP) | VAF 120/403 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.869); catalogued as rs1217346110, COSV100497813; called by muse, varscan2
- DCAF12L1 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100948149, COSV64421461; called by muse, mutect2, varscan2
- DCAF16 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.969); catalogued as COSV101200401; called by muse, mutect2, varscan2
- DCAF6 | c.1374G>C p.Q458H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV100394034; called by muse, mutect2, varscan2
- DCDC1 | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV100662939; called by muse, mutect2
- DCLK3 | c.824G>T p.W275L | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV101373913; called by muse, mutect2, varscan2
- DDHD1 | c.1070G>T p.R357L (on ENST00000323669; = p.R554L on NM_030637.3) | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100079220, COSV60360644, COSV60361245; called by muse, mutect2, varscan2
- DDI1 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56370050, COSV56390070; called by muse, mutect2, varscan2
- DDR2 | c.215G>T p.W72L | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906271; called by muse, mutect2, varscan2
- DENND1A | c.1732C>G p.L578V | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV101011859, COSV65355429; called by muse, mutect2, varscan2
- DENND4A | c.3415G>A p.A1139T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV101475281; called by muse, mutect2
- DENND4A | c.2575A>C p.T859P | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.359); catalogued as COSV101475282; called by muse, mutect2
- DERA | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1326271196, COSV101397333; called by muse, mutect2
- DGKI | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99932988; called by muse, mutect2, varscan2
- DGKZ | c.1288C>A p.P430T (on ENST00000454345 / NM_001105540.2; = p.P242T on NM_003646.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100551184; called by muse, mutect2, varscan2
- DHCR7 | c.739G>C p.A247P | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100831779, COSV62795146, COSV62796610; called by muse, mutect2, varscan2
- DIO2 | c.140C>A p.T47N | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as COSV70446131; called by muse, mutect2, varscan2
- DIP2A | c.4567G>T p.E1523* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV100595434; called by muse, mutect2, varscan2
- DISP2 | c.1549C>A p.L517M | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.543); catalogued as COSV99139784; called by muse, mutect2, varscan2
- DLGAP3 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV52392258, COSV52396866, COSV99332347; called by muse, mutect2
- DLGAP4 | c.1525C>A p.R509S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100210957; called by muse, mutect2
- DMD | c.4839G>T p.W1613C | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100818646, COSV63777952; called by muse, mutect2, varscan2
- DMGDH | c.1817G>C p.W606S | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99668606; called by muse, mutect2
- DMGDH | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99668610; called by muse, mutect2
- DMRT1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 15/132 reads (11%) | catalogued as COSV101206627, COSV66519522; called by muse, mutect2, varscan2
- DMRTB1 | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101008264; called by muse, mutect2, varscan2
- DMRTB1 | c.967C>A p.Q323K | Missense Mutation (SNP) | VAF 165/789 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV101008265; called by muse, mutect2, varscan2
- DNAAF1 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100533548; called by muse, mutect2, varscan2
- DNAH2 | c.10811G>C p.R3604P | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101209093; called by muse, mutect2
- DNAH3 | c.5506G>A p.D1836N | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs760215651, COSV99765718; called by muse, mutect2, varscan2
- DNAH8 | c.9613C>G p.P3205A | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); catalogued as rs1465517548, COSV100543883; called by muse, mutect2
- DNAH9 | c.3944G>T p.S1315I | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV99304808; called by muse, mutect2, varscan2
- DNER | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100518630; called by muse, mutect2, varscan2
- DOCK9 | c.3072C>A p.S1024R (on ENST00000376460 / NM_001366676.2; = p.S1025R on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100238375; called by muse, mutect2, varscan2
- DPF3 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100818446; called by muse, varscan2
- DPP6 | c.2271G>C p.L757F (on ENST00000377770 / NM_001364500.2; = p.L695F on NM_001936.5) | Missense Mutation (SNP) | VAF 95/544 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV100123848; called by muse, mutect2, varscan2
- DPYS | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100679391; called by muse, mutect2, varscan2
- DRD2 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100669385; called by muse, mutect2, varscan2
- DRP2 | c.1495G>C p.G499R | Missense Mutation (SNP) | VAF 96/430 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871835; called by muse, mutect2, varscan2
- DSC2 | c.1231A>T p.K411* | Nonsense Mutation (SNP) | VAF 37/193 reads (19%) | catalogued as COSV99199541; called by muse, mutect2, varscan2
- DSG1 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV99935692; called by muse, mutect2, varscan2
- DSG1 | c.1274T>C p.M425T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV99935693; called by muse, mutect2, varscan2
- DSG2 | c.2539A>T p.I847L | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99852919; called by muse, mutect2, varscan2
- DSG2 | c.2637G>C p.E879D | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as COSV99852922; called by muse, mutect2, varscan2
- DSG3 | c.2569G>T p.A857S | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745894884, COSV99933901; called by muse, mutect2, varscan2
- DST | c.10019G>T p.G3340V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs1470395488, COSV99752690; called by muse, mutect2
- DTNA | c.1913A>T p.E638V | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV99311487; called by muse, mutect2, varscan2
- DTX3 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 42/748 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.908); catalogued as COSV54091239, COSV99677671; called by muse, mutect2
- DUOX2 | c.4532A>T p.K1511M | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101199626; called by muse, mutect2, varscan2
- DUOX2 | c.4171C>T p.P1391S | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as CM160660, COSV66534827; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.886A>T p.I296F | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs907231584, COSV99143605; called by muse, mutect2, varscan2
- DUSP21 | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.024); catalogued as COSV100173528; called by muse, mutect2, varscan2
- DYNC2H1 | c.1459G>T p.V487F | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100517883; called by muse, varscan2
- DYNC2H1 | c.12196G>T p.D4066Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as rs754751572, COSV100517884, COSV62096496; called by muse, mutect2, varscan2
- DYNC2I1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV101337624; called by muse, mutect2
- DYRK3 | c.1115C>G p.S372C | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100895639; called by muse, mutect2, varscan2
- EBF3 | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 45/237 reads (19%) | catalogued as COSV100799098, COSV62479505; called by muse, mutect2, varscan2
- EFCAB5 | c.4486C>G p.P1496A | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV100299919, COSV57929981; called by muse, mutect2, varscan2
- EGFR | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 90/520 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51866279, COSV99288189; called by muse, varscan2
- EGFR | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV51845994, COSV99288202; called by muse, mutect2
- EIF4G3 | c.2554G>C p.D852H | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51684662; called by muse, mutect2
- EIF6 | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 109/489 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV99863700; called by muse, mutect2, varscan2
- ELAC2 | c.570G>T p.R190S | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100568398; called by muse, mutect2
- ELMO1 | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV60302137; called by mutect2, varscan2
- ELMOD3 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV100226124; called by muse, mutect2, varscan2
- ELMOD3 | c.199+1G>T p.X67_splice | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100226127; called by muse, mutect2, varscan2
- ELP2 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100626755, COSV60852564; called by muse, mutect2, varscan2
- ELP6 | c.324-2A>T p.X108_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99948092; called by muse, mutect2
- EMC7 | c.723G>T p.R241S | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99854761; called by muse, mutect2
- EMILIN3 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 12/235 reads (5%) | catalogued as COSV100182449; called by muse, mutect2
- ENOX1 | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as rs1386716095, COSV99815401; called by muse, mutect2, varscan2
- EOLA1 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100828397; called by muse, mutect2
- EPB41L2 | c.1849G>T p.V617L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.084); catalogued as COSV100440379; called by muse, mutect2, varscan2
- EPHA1 | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 49/872 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99313652; called by muse, mutect2
- EPHA6 | c.1877T>A p.F626Y | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV101061258; called by muse, mutect2, varscan2
- EPHB1 | c.2304C>G p.Y768* | Nonsense Mutation (SNP) | VAF 18/181 reads (10%) | catalogued as COSV101212851; called by muse, mutect2, varscan2
- EPRS1 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100859335; called by muse, mutect2
- ERBB4 | c.2766T>A p.D922E | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV100724061; called by muse, mutect2, varscan2
- ERCC6 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV100875788; called by muse, mutect2
- ERCC6 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100875790; called by muse, mutect2, varscan2
- ERICH3 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100443731; called by muse, mutect2
- ERMN | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs1448898712; called by muse, mutect2
- ESR2 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 225/680 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99962940; called by muse, mutect2, varscan2
- ETNPPL | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.364); catalogued as COSV99625051; called by muse, mutect2
- ETV3L | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV101485566; called by muse, mutect2, varscan2
- ETV5 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 69/534 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV100112151; called by muse, mutect2, varscan2
- EVX2 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV100420595; called by muse, mutect2
- EXO1 | c.362G>C p.R121P | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100799662; called by muse, mutect2, varscan2
- EXPH5 | c.2261A>G p.N754S | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as COSV99761171; called by muse, mutect2, varscan2
- EYS | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1183176426, COSV100675922; called by muse, mutect2
- F5 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190555110, COSV100888985; called by muse, mutect2, varscan2
- FAM135B | c.2811G>T p.L937F | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99420764; called by muse, mutect2, varscan2
- FAM13A | c.1688C>G p.S563W | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99983076; called by muse, mutect2, varscan2
- FAM171B | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100488355; called by muse, mutect2
- FAM177A1 | c.128A>G p.E43G (on ENST00000382406 / NM_001289022.2; = p.E66G on NM_173607.5) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99805744; called by muse, mutect2, varscan2
- FAM184A | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 12/177 reads (7%) | catalogued as COSV100137524, COSV99055183; called by muse, mutect2
- FAM47C | c.661C>A p.H221N | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs782141176, COSV100792375; called by muse, mutect2, varscan2
- FAM47C | c.2842G>T p.G948W | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs782306470, COSV63723870; called by muse, mutect2, varscan2
- FAM83B | c.608G>T p.R203M | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174180; called by muse, mutect2, varscan2
- FAM98C | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53039498, COSV99384885; called by muse, varscan2
- FAT3 | c.3507G>T p.Q1169H | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV53091797, COSV99963312; called by muse, mutect2
- FAT4 | c.3020A>T p.E1007V | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101272153; called by muse, mutect2, varscan2
- FAT4 | c.13196G>T p.G4399V | Missense Mutation (SNP) | VAF 78/695 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100627671; called by muse, varscan2
- FBLN1 | c.1407C>A p.Y469* | Nonsense Mutation (SNP) | VAF 20/172 reads (12%) | catalogued as COSV99410216; called by muse, mutect2, varscan2
- FBXO21 | c.1587G>T p.M529I (on ENST00000330622 / NM_033624.3; = p.M522I on NM_015002.3) | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100401637; called by muse, mutect2, varscan2
- FBXO3 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 70/602 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV55768154, COSV99682112; called by muse, mutect2, varscan2
- FBXW10 | c.2021C>T p.T674I | Missense Mutation (SNP) | VAF 91/311 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100111272; called by muse, mutect2, varscan2
- FCRL5 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62521002; called by muse, mutect2, varscan2
- FER1L6 | c.5104C>A p.L1702M | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101205584; called by muse, mutect2, varscan2
- FGF13 | c.602-1G>T p.X201_splice | Splice Site (SNP) | VAF 28/81 reads (35%) | catalogued as COSV100263819, COSV59545683; called by muse, mutect2, varscan2
- FGF14 | c.740C>G p.T247R | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as COSV101085197; called by muse, mutect2, varscan2
- FILIP1 | c.3452C>T p.S1151L | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.065); catalogued as COSV99384145; called by muse, mutect2
- FKBP6 | c.318G>C p.E106D | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99333819; called by muse, mutect2, varscan2
- FLG | c.10586C>A p.P3529H | Missense Mutation (SNP) | VAF 350/926 reads (38%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.984); catalogued as COSV100911114, COSV64244161; called by muse, mutect2, varscan2
- FLG | c.5008C>A p.Q1670K | Missense Mutation (SNP) | VAF 637/1493 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.262); catalogued as COSV100911119; called by muse, mutect2, varscan2
- FLG | c.3685G>T p.G1229C | Missense Mutation (SNP) | VAF 100/1207 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV100911121; called by muse, mutect2
- FLG2 | c.3809C>A p.S1270Y | Missense Mutation (SNP) | VAF 68/702 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV101165683; called by muse, mutect2
- FMN2 | c.4699C>T p.Q1567* | Nonsense Mutation (SNP) | VAF 24/628 reads (4%) | catalogued as COSV60428057; called by muse, mutect2
- FOXI2 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV100510960; called by muse, mutect2, varscan2
- FOXP4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 23/369 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.92); catalogued as COSV57219622; called by muse, mutect2
- FPR2 | c.118G>T p.G40W | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100389176; called by muse, mutect2, varscan2
- FREM1 | c.842G>T p.W281L | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100772184; called by muse, mutect2, varscan2
- FREM2 | c.7558G>T p.E2520* | Nonsense Mutation (SNP) | VAF 26/142 reads (18%) | catalogued as COSV99747522; called by muse, mutect2, varscan2
- FRRS1 | c.1121-1G>T p.X374_splice | Splice Site (SNP) | VAF 15/147 reads (10%) | catalogued as COSV99789751; called by muse, mutect2
- FRY | c.5463G>T p.K1821N | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV100968917, COSV100969772; called by muse, mutect2, varscan2
- FRYL | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99976273; called by muse, mutect2, varscan2
- FSCB | c.610A>T p.S204C | Missense Mutation (SNP) | VAF 19/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100469005; called by muse, mutect2
- FSHR | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 11/105 reads (10%) | catalogued as COSV100436760; called by muse, mutect2
- FSIP2 | c.18725C>A p.P6242H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100554434; called by muse, mutect2, varscan2
- FSIP2 | c.19601C>A p.P6534Q | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554437; called by muse, mutect2, varscan2
- FSTL5 | c.2416T>C p.F806L | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100053612; called by muse, mutect2, varscan2
- FURIN | c.1258G>T p.V420L | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99184628; called by muse, mutect2, varscan2
- GABBR1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 22/472 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100589518; called by muse, mutect2
- GABRA2 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV62912841; called by muse, mutect2
- GABRB2 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99195758; called by muse, mutect2, varscan2
- GABRB3 | c.876C>A p.H292Q | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV100158842; called by muse, varscan2
- GAL3ST1 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs560164540, COSV100142969; called by muse, mutect2, varscan2
- GAL3ST4 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV99444431; called by muse, mutect2
- GALNT13 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101222349, COSV67210822; called by muse, mutect2
- GALNT14 | c.687T>A p.D229E | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100204290; called by muse, varscan2
- GALNT16 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1192437702, COSV61886909; called by muse, mutect2
- GALNT18 | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 18/154 reads (12%) | catalogued as COSV99924093; called by muse, mutect2, varscan2
- GALNTL6 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV101550690; called by muse, mutect2, varscan2
- GAP43 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 26/201 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100525384; called by muse, mutect2, varscan2
- GAPDHS | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 36/365 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV99722697; called by muse, mutect2, varscan2
- GAPDHS | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 37/364 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.422); catalogued as rs763165514, COSV99722699; called by muse, mutect2, varscan2
- GAS7 | c.954C>A p.C318* (on ENST00000432992 / NM_201433.2; = p.C178* on NM_003644.3) | Nonsense Mutation (SNP) | VAF 31/155 reads (20%) | catalogued as COSV100094885, COSV60438000; called by muse, mutect2, varscan2
- GBP4 | c.1217A>C p.K406T | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100864330; called by muse, mutect2
- GBP6 | c.1425G>C p.L475F | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV100969495; called by muse, mutect2, varscan2
- GCFC2 | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100319440; called by muse, mutect2, varscan2
- GIMAP1 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 12/158 reads (8%) | catalogued as COSV100211996, COSV56189241; called by muse, mutect2
- GJA9 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 13/251 reads (5%) | catalogued as COSV100668048; called by muse, mutect2
- GJB3 | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV100973977; called by muse, mutect2
- GJC1 | c.483G>T p.K161N | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100395138; called by muse, mutect2
- GLI1 | c.1213C>G p.R405G | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.181); catalogued as COSV57366679, COSV99953804; called by muse, mutect2, varscan2
- GNB3 | c.443G>T p.C148F | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV99300978; called by muse, mutect2, varscan2
- GNL2 | c.1866C>T p.V622= | Splice Region (SNP) | VAF 40/440 reads (9%) | catalogued as COSV99953522; called by muse, mutect2
- GOLGA1 | c.1382A>T p.H461L | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.477); catalogued as COSV101001980; called by muse, mutect2, varscan2
- GPATCH2 | c.961G>T p.V321F | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); catalogued as COSV100861362; called by muse, mutect2, varscan2
- GPR137B | c.547G>T p.G183* | Nonsense Mutation (SNP) | VAF 15/155 reads (10%) | catalogued as COSV100858330; called by muse, mutect2, varscan2
- GPR158 | c.1510C>T p.H504Y | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100892969; called by muse, mutect2
- GPR22 | c.216A>T p.L72F | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV99771597; called by muse, mutect2, varscan2
- GPR78 | c.712C>A p.R238S | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101223942; called by muse, mutect2, varscan2
- GPR83 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99703603; called by muse, mutect2, varscan2
- GPR85 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51783474, COSV51785882; called by muse, mutect2, varscan2
- GPRIN1 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV99991213; called by muse, mutect2, varscan2
- GRID1 | c.800T>C p.I267T | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100022640; called by muse, mutect2, varscan2
- GRIK2 | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 55/602 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100024197, COSV59763000; called by muse, mutect2
- GRIN2A | c.3600C>A p.H1200Q | Missense Mutation (SNP) | VAF 155/828 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.139); catalogued as COSV100408855, COSV58023608; called by muse, varscan2
- GRIN2A | c.3146del p.P1049Lfs*58 | Frame Shift Del (DEL) | VAF 73/435 reads (17%) | catalogued as COSV58038797; called by pindel, varscan2*
- GRM7 | c.1157C>A p.T386K | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.142); catalogued as COSV100735945; called by muse, mutect2, varscan2
- GTF3C2 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99272354, COSV99272534; called by mutect2, varscan2
- GTPBP1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53284411; called by muse, mutect2, varscan2
- GUCY1A1 | c.1408C>A p.Q470K | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99637365; called by muse, mutect2, varscan2
- GUCY1B1 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99072720; called by muse, mutect2, varscan2
- GUCY2C | c.2250-1G>A p.X750_splice | Splice Site (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99663377; called by muse, mutect2, varscan2
- GZMB | c.574C>G p.P192A | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV99362240, COSV99362473; called by muse, mutect2, varscan2
- H2AC6 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100019801; called by muse, mutect2, varscan2
- H2BC7 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100587121; called by muse, mutect2, varscan2
- H3C1 | c.331T>A p.C111S | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV99771954; called by muse, mutect2, varscan2
- H3C2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV52517721, COSV52518221; called by muse, mutect2, varscan2
- H3C8 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); catalogued as COSV100010053, COSV59952719; called by muse, mutect2
- HADHB | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs374979465; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAPLN1 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs765478241, COSV99164703; called by muse, varscan2
- HAPLN1 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99164705; called by muse, mutect2, varscan2
- HAUS1 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99959382; called by muse, mutect2, varscan2
- HAUS6 | c.2598G>C p.L866F | Missense Mutation (SNP) | VAF 123/354 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.742); catalogued as COSV100997781; called by muse, mutect2, varscan2
- HCK | c.183G>A p.P61= | Splice Region (SNP) | VAF 19/110 reads (17%) | catalogued as rs1435925519, COSV99393863; called by muse, mutect2, varscan2
- HCRTR2 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV100904231, COSV63795269; called by muse, mutect2
- HCRTR2 | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV100904232; called by muse, mutect2
- HCST | c.241+1G>T p.X81_splice | Splice Site (SNP) | VAF 8/55 reads (15%) | catalogued as COSV99385538; called by muse, mutect2, varscan2
- HDAC4 | c.2402G>T p.G801V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100612902; called by muse, mutect2
- HDAC4 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV100612907; called by muse, mutect2
- HDC | c.568T>A p.S190T | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99983901; called by muse, mutect2
- HDGF | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100625653; called by muse, mutect2, varscan2
- HDLBP | c.848G>T p.R283L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV100190133, COSV60495928; called by muse, mutect2, varscan2
- HECW1 | c.605G>C p.R202P | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779347290, COSV101223022, COSV67831867; called by muse, mutect2, varscan2
- HECW1 | c.3852T>A p.F1284L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101223024; called by muse, mutect2, varscan2
- HEPHL1 | c.3191C>A p.T1064K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs754052406, COSV100243666; called by muse, mutect2, varscan2
- HGF | c.1777T>G p.F593V | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.176); catalogued as COSV99736039; called by muse, mutect2
- HGF | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99736042; called by muse, mutect2, varscan2
- HGSNAT | c.1056G>T p.L352F | Missense Mutation (SNP) | VAF 185/744 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as COSV99925147; called by muse, mutect2, varscan2
- HIP1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417171; called by muse, mutect2, varscan2
- HK3 | c.1032A>T p.Q344H | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99458029; called by muse, mutect2
- HLTF | c.2343A>T p.K781N | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100026754; called by muse, mutect2, varscan2
- HLTF | c.550A>T p.S184C | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV100026756; called by muse, mutect2
- HMCN1 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99625821; called by muse, mutect2
- HMGXB4 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99329963; called by muse, mutect2, varscan2
- HOXA1 | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100547325, COSV100547408; called by muse, mutect2
- HOXD3 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99979991; called by muse, mutect2
- HPS1 | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100282408; called by muse, mutect2, varscan2
- HR | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as COSV100455701, COSV100456061; called by muse, mutect2, varscan2
- HRC | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs528365011; called by muse, mutect2, varscan2
- HRNR | c.1828C>A p.H610N | Missense Mutation (SNP) | VAF 84/1098 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100913112; called by muse, mutect2
- HSD3B2 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs139191056; called by muse, mutect2, varscan2
- HSPA1L | c.1898C>T p.T633I | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as COSV100989484; called by muse, mutect2, varscan2
- HTR1E | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 19/205 reads (9%) | catalogued as COSV100541001; called by muse, mutect2
- HUWE1 | c.10546G>T p.A3516S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs915089345, COSV99471105; called by muse, mutect2, varscan2
- HUWE1 | c.1805G>T p.G602V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53345447, COSV99471108; called by muse, mutect2, varscan2
- HYDIN | c.11455C>A p.Q3819K | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101124967; called by muse, mutect2, varscan2
- HYDIN | c.4334G>T p.G1445V | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66834177; called by muse, mutect2, varscan2
- IARS1 | c.3165A>T p.Q1055H | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100986678, COSV65113604; called by muse, mutect2, varscan2
- IFIT1B | c.1037T>A p.L346Q | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100879056; called by muse, mutect2, varscan2
- IFNA13 | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV101489472; called by muse, mutect2, varscan2
- IGFBP1 | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV51874290, COSV99298670; called by muse, mutect2
- IGFBP1 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV99298673; called by muse, mutect2
- IGKV1-27 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs778478221; called by muse, mutect2, varscan2
- IGSF10 | c.4597A>T p.K1533* | Nonsense Mutation (SNP) | VAF 33/311 reads (11%) | catalogued as COSV99177106; called by muse, mutect2, varscan2
- IGSF3 | c.2074G>T p.V692L (on ENST00000369486 / NM_001007237.3; = p.V712L on NM_001542.4) | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as COSV100604230; called by muse, mutect2
- IKZF1 | c.236C>A p.A79E | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV100498126, COSV58786494; called by muse, mutect2, varscan2
- IL21R | c.1395G>T p.W465C | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100559907; called by muse, mutect2, varscan2
- IL3 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 54/693 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.415); catalogued as COSV99735260; called by muse, mutect2
- IMMP2L | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV100068813; called by muse, mutect2, varscan2
- INPP4B | c.2494C>A p.R832S | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53711774, COSV53727337; called by muse, mutect2, varscan2
- INPP4B | c.2493C>A p.C831* | Nonsense Mutation (SNP) | VAF 15/146 reads (10%) | catalogued as COSV99523439; called by muse, mutect2, varscan2
- INPP4B | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99523440; called by muse, mutect2
- INTS4 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV101417145; called by muse, mutect2
- INTS4 | c.676G>T p.G226* | Nonsense Mutation (SNP) | VAF 26/222 reads (12%) | catalogued as COSV101417149; called by muse, mutect2
- INTS6L | c.1287+1G>T p.X429_splice | Splice Site (SNP) | VAF 207/250 reads (83%) | catalogued as COSV100878043; called by muse, mutect2, varscan2
- IQGAP2 | c.2391T>A p.D797E | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99166837; called by muse, mutect2, varscan2
- IQGAP3 | c.544T>C p.Y182H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100752097; called by muse, mutect2
- IQSEC3 | c.1042C>A p.P348T (on ENST00000538872 / NM_001170738.2; = p.P45T on NM_015232.1) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as rs375324399; called by muse, mutect2
- IQSEC3 | c.1242C>G p.D414E (on ENST00000538872 / NM_001170738.2; = p.D111E on NM_015232.1) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100406946; called by muse, mutect2
- IQUB | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV61239985; called by muse, mutect2, varscan2
- IREB2 | c.877G>T p.G293W | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99359150; called by muse, mutect2, varscan2
- IRGC | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV99746135; called by muse, mutect2, varscan2
- ISM1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV99339677; called by muse, varscan2
- ISX | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.539); catalogued as rs764566112, COSV100434027; called by muse, mutect2, varscan2
- ITGA11 | c.1014G>C p.L338F | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100241144; called by muse, mutect2
- ITGA4 | c.2275C>A p.L759I | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as COSV101223181; called by muse, mutect2, varscan2
- ITGAL | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 104/392 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV100776129; called by muse, mutect2, varscan2
- ITGAL | c.1963C>A p.Q655K | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as COSV100776130; called by muse, mutect2, varscan2
- ITGAX | c.1585G>T p.G529W | Missense Mutation (SNP) | VAF 81/412 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204936957, COSV99191532; called by muse, mutect2, varscan2
- ITGB5 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs753371523, COSV99950470; called by muse, mutect2, varscan2
- ITGBL1 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101095173; called by muse, mutect2, varscan2
- ITLN1 | c.715A>T p.R239W | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV100406145; called by muse, mutect2
- ITPR3 | c.3889G>T p.V1297L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV100967080; called by muse, mutect2, varscan2
- ITPR3 | c.4411G>T p.V1471F | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.769); catalogued as COSV100967082; called by muse, mutect2, varscan2
- ITPRID1 | c.22G>T p.G8* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100085912; called by muse, mutect2
- ITSN1 | c.2347G>T p.G783C | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156923746, COSV101180456; called by muse, mutect2, varscan2
- JMY | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV101267964; called by muse, mutect2, varscan2
- JPH3 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | catalogued as COSV99413018; called by muse, mutect2, varscan2
- JPT2 | c.550A>T p.K184* | Nonsense Mutation (SNP) | VAF 76/265 reads (29%) | catalogued as COSV99936019; called by muse, mutect2, varscan2
- KCNA1 | c.1478C>A p.T493N | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs757648784, COSV101230164; called by muse, varscan2
- KCNAB2 | c.362G>T p.W121L | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51238950, COSV99378777; called by muse, mutect2, varscan2
- KCNF1 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV99705592; called by muse, mutect2, varscan2
- KCNG3 | c.1285A>T p.S429C | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100044843; called by muse, mutect2, varscan2
- KCNH2 | c.2155G>T p.G719C | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100059442; called by muse, mutect2
- KCNH3 | c.2696T>G p.L899R | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99234905; called by muse, mutect2, varscan2
- KCNH3 | c.2797G>A p.G933R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.996); catalogued as rs748380609, COSV57791744; called by muse, mutect2, varscan2
- KCNJ1 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100131280; called by muse, mutect2, varscan2
- KCNJ12 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59176557; called by muse, mutect2, varscan2
- KCNK17 | c.688+1G>T p.X230_splice | Splice Site (SNP) | VAF 20/316 reads (6%) | catalogued as COSV100950105; called by muse, mutect2
- KCNMA1 | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99695764; called by muse, mutect2, varscan2
- KCNMA1 | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99695773; called by muse, mutect2, varscan2
- KCNT1 | c.2314G>A p.E772K (on ENST00000488444; = p.E791K on NM_020822.3) | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.284); catalogued as COSV99705268; called by muse, mutect2, varscan2
- KCNT2 | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99652291; called by muse, mutect2, varscan2
- KCNU1 | c.3128G>T p.C1043F | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV101299029; called by muse, mutect2, varscan2
- KCTD20 | c.173A>C p.D58A | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as COSV99535863; called by muse, mutect2, varscan2
- KDM4D | c.946A>T p.R316W | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100624175; called by muse, varscan2
- KDM5B | c.2019A>T p.G673= | Splice Region (SNP) | VAF 33/144 reads (23%) | catalogued as rs766135362, COSV99350251; called by muse, mutect2, varscan2
- KDR | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55758612; called by muse, mutect2, varscan2
- KHK | c.624G>C p.L208F | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99565048; called by muse, mutect2, varscan2
- KIAA0513 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as rs765234144, COSV50745252, COSV99260606; called by muse, mutect2, varscan2
- KIAA1549L | c.2437G>C p.G813R (on ENST00000321505; = p.G1110R on NM_012194.3) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99682882; called by muse, mutect2, varscan2
- KIAA1614 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as COSV100851278; called by muse, mutect2
- KIF13A | c.2687G>C p.W896S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99434652; called by muse, mutect2
- KIF21A | c.1400G>T p.R467I | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV62775173; called by muse, mutect2, varscan2
- KIF26B | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.08); catalogued as COSV101313790; called by muse, mutect2, varscan2
- KIF5A | c.1417C>A p.L473M | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99672620; called by muse, mutect2, varscan2
- KLF14 | c.655C>A p.H219N | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV100205846; called by muse, mutect2, varscan2
- KLHL20 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99268226; called by muse, mutect2, varscan2
- KLHL32 | c.59A>T p.H20L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1488022653; called by muse, mutect2
- KLHL7 | c.1061G>C p.C354S (on ENST00000339077 / NM_001031710.3; = p.C306S on NM_018846.5) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.536); catalogued as COSV100177831; called by muse, mutect2, varscan2
- KMO | c.1064C>G p.A355G | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779550491, COSV59364691, COSV59366341, COSV59366427; called by muse, mutect2, varscan2
- KNTC1 | c.6214C>T p.P2072S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs377336279; called by muse, mutect2, varscan2
- KPNA6 | c.559-2A>T p.X187_splice | Splice Site (SNP) | VAF 19/114 reads (17%) | catalogued as COSV101012452; called by muse, mutect2, varscan2
- KRT6B | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 38/547 reads (7%) | catalogued as COSV52883271, COSV99360540; called by muse, mutect2
- KRT71 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99922020; called by muse, mutect2, varscan2
- KRTAP10-10 | c.170G>T p.C57F | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100552375; called by muse, mutect2, varscan2
- KRTAP13-3 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100481722; called by muse, mutect2, varscan2
- KRTAP20-1 | c.158A>T p.Y53F | Missense Mutation (SNP) | VAF 32/232 reads (14%) | PolyPhen benign (0.003); catalogued as COSV100228722; called by muse, mutect2, varscan2
- KRTAP21-2 | c.157T>A p.Y53N | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.346); catalogued as COSV100441116; called by muse, mutect2, varscan2
- KRTAP6-2 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 20/157 reads (13%) | PolyPhen possibly damaging (0.591); catalogued as COSV100588899, COSV100588970; called by muse, mutect2, varscan2
- KRTCAP2 | c.159+2T>C p.X53_splice | Splice Site (SNP) | VAF 35/166 reads (21%) | catalogued as rs1441988191, COSV99825893; called by muse, mutect2, varscan2
- LACC1 | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV100354628; called by muse, mutect2
- LAMA1 | c.7455C>A p.P2485= | Splice Region (SNP) | VAF 9/79 reads (11%) | catalogued as COSV101055519; called by muse, mutect2
- LAMA1 | c.7036G>T p.G2346C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV101055521; called by muse, mutect2
- LAMA1 | c.345+2T>C p.X115_splice | Splice Site (SNP) | VAF 17/68 reads (25%) | catalogued as COSV101055522; called by muse, mutect2, varscan2
- LAMA4 | c.2021A>G p.N674S (on ENST00000230538 / NM_001105206.3; = p.N667S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100037853; called by muse, mutect2, varscan2
- LAMB4 | c.4971C>A p.H1657Q | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99223246; called by muse, mutect2, varscan2
- LAMC3 | c.1789G>T p.A597S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV100735913; called by muse, varscan2
- LARS1 | c.3274A>T p.N1092Y (on ENST00000394434 / NM_020117.11; = p.N1065Y on NM_016460.3) | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99198513; called by muse, mutect2, varscan2
- LAX1 | c.495del p.N166Tfs*41 | Frame Shift Del (DEL) | VAF 17/145 reads (12%) | catalogued as COSV100920107; called by mutect2, varscan2
- LCA5 | c.1538A>T p.E513V | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100878200; called by muse, mutect2
- LCE1C | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.866); catalogued as rs1369001286, COSV100908420; called by muse, mutect2, varscan2
- LCE1E | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.823); catalogued as COSV100908522; called by muse, varscan2
- LCE2B | c.307T>A p.C103S | Missense Mutation (SNP) | VAF 93/297 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.088); catalogued as COSV100909288; called by muse, mutect2, varscan2
- LCT | c.3232del p.E1078Nfs*6 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | catalogued as COSV51549946; called by mutect2, pindel, varscan2
- LDB2 | c.458T>A p.M153K | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100453003; called by muse, mutect2, varscan2
- LEF1 | c.1151A>T p.Q384L | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV99489387; called by muse, mutect2
- LIG4 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as COSV100799761; called by muse, mutect2, varscan2
- LILRB4 | c.428T>A p.L143Q | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV99553598; called by muse, mutect2, varscan2
- LIMD1 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99836834; called by muse, mutect2, varscan2
- LINGO1 | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.568); catalogued as COSV100796322, COSV62437647; called by muse, mutect2, varscan2
- LMAN1L | c.1316G>A p.G439D | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs567781867, COSV100547610; called by muse, mutect2, varscan2
- LMBR1 | c.1024A>G p.T342A | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as rs1243498576, COSV100626590; called by muse, mutect2
- LMBR1L | c.1402+1G>T p.X468_splice | Splice Site (SNP) | VAF 48/353 reads (14%) | catalogued as COSV99908777; called by muse, mutect2, varscan2
- LMO2 | c.376C>G p.Q126E (on ENST00000395833 / NM_001142315.2; = p.Q195E on NM_005574.4) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as COSV99137778; called by muse, mutect2
- LMOD2 | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101505399, COSV101505422; called by muse, mutect2
- LONRF3 | c.2223G>T p.K741N (on ENST00000371628 / NM_001031855.3; = p.K700N on NM_024778.5) | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756722628, COSV100504285; called by muse, mutect2, varscan2
- LPA | c.5269C>A p.P1757T | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100306361; called by muse, mutect2
- LPA | c.4613C>A p.P1538Q | Missense Mutation (SNP) | VAF 31/444 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100306364; called by muse, mutect2
- LPCAT2 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100044534; called by muse, mutect2, varscan2
- LRIT3 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV100015939; called by muse, mutect2
- LRP1 | c.2703G>T p.K901N | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99675005; called by muse, mutect2, varscan2
- LRP12 | c.2128G>T p.D710Y | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as COSV99407373; called by muse, mutect2
- LRP12 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as COSV99407377; called by muse, mutect2, varscan2
- LRP1B | c.13025G>A p.S4342N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV67198112; called by muse, mutect2, varscan2
- LRP1B | c.7982G>T p.G2661V | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101254102; called by muse, mutect2
- LRP1B | c.5151G>T p.M1717I | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV67255478; called by muse, mutect2, varscan2
- LRP1B | c.3661C>A p.H1221N | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV101253469; called by muse, mutect2, varscan2
- LRP1B | c.1446G>C p.M482I | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101249865, COSV101254107; called by muse, mutect2, varscan2
- LRP2 | c.9661C>T p.L3221F | Missense Mutation (SNP) | VAF 29/300 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1172905703; called by muse, mutect2
- LRRC6 | c.653+1G>T p.X218_splice | Splice Site (SNP) | VAF 31/241 reads (13%) | catalogued as CS137153, COSV99137818; called by muse, mutect2, varscan2
- LRRC66 | c.2299A>C p.K767Q | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100602866; called by muse, mutect2
- LRRC66 | c.1213T>C p.W405R | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.131); catalogued as COSV100602868; called by muse, mutect2
- LRRC7 | c.3566G>T p.G1189V (on ENST00000651989 / NM_001370785.2; = p.G1156V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV99225280; called by muse, mutect2
- LRRN2 | c.1892T>A p.L631H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.635); catalogued as COSV100912782; called by muse, mutect2, varscan2
- LRRN3 | c.1188C>G p.C396W | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100068814, COSV57824253; called by muse, mutect2, varscan2
- LRRTM4 | c.426C>A p.Y142* | Nonsense Mutation (SNP) | VAF 27/119 reads (23%) | catalogued as COSV101297455; called by muse, mutect2, varscan2
- LTN1 | c.5132G>T p.G1711V | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100797917; called by muse, mutect2, varscan2
- LTN1 | c.810+1G>T p.X270_splice | Splice Site (SNP) | VAF 13/77 reads (17%) | catalogued as COSV100797918; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.556G>T p.G186W | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV101012186; called by muse, mutect2
- LYN | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV101319586; called by muse, mutect2, varscan2
- MAGEC1 | c.2303A>T p.E768V | Missense Mutation (SNP) | VAF 44/373 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV99595147; called by muse, mutect2, varscan2
- MAGEH1 | c.612G>C p.E204D | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.926); catalogued as COSV100746790; called by muse, mutect2, varscan2
- MAGEL2 | c.2343G>T p.E781D | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as rs772413215, COSV100045805, COSV100046119; called by muse, mutect2, varscan2
- MAGI2 | c.3398C>A p.P1133H | Missense Mutation (SNP) | VAF 69/329 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100833640; called by muse, mutect2, varscan2
- MAP3K15 | c.3316C>T p.H1106Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.332); catalogued as COSV100134325; called by muse, mutect2, varscan2
- MAP7D2 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 62/160 reads (39%) | catalogued as COSV101107228; called by muse, mutect2, varscan2
- MAPK9 | c.236G>T p.C79F | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.391); catalogued as COSV100558201; called by muse, mutect2, varscan2
- MARCHF6 | c.2373+1G>T p.X791_splice | Splice Site (SNP) | VAF 9/79 reads (11%) | catalogued as COSV99929454; called by muse, mutect2, varscan2
- MARCO | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.459); catalogued as rs773925484, COSV100503279, COSV59051612; called by muse, mutect2, varscan2
- MATN2 | c.1479T>A p.H493Q | Missense Mutation (SNP) | VAF 90/203 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99645892; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MBP | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 22/147 reads (15%) | catalogued as COSV100592505, COSV63556473; called by muse, mutect2, varscan2
- MECP2 | c.149C>G p.A50G | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV100317937; called by muse, mutect2
- MED12L | c.6295C>T p.Q2099* | Nonsense Mutation (SNP) | VAF 19/152 reads (13%) | catalogued as COSV99852030; called by muse, mutect2, varscan2
- MED23 | c.2609C>G p.A870G | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100644836; called by muse, mutect2, varscan2
- MED27 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 18/175 reads (10%) | catalogued as rs200793719, COSV99406411; called by muse, mutect2, varscan2
- MEIS1 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 77/325 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55487037; called by muse, mutect2, varscan2
- MEPE | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV100734898; called by muse, mutect2, varscan2
- MGAT1 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 32/171 reads (19%) | PolyPhen benign (0.304); catalogued as COSV100286570; called by muse, mutect2, varscan2
- MGAT5 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 103/463 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99924214; called by muse, mutect2, varscan2
- MIPEP | c.1826G>T p.G609V | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as COSV101193040; called by muse, mutect2, varscan2
- MIPEP | c.1825G>T p.G609C | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.774); catalogued as rs779028923, COSV101193041; called by muse, mutect2, varscan2
- MLLT10 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100307666; called by muse, mutect2
- MMP12 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100404852; called by muse, mutect2
- MMP16 | c.597T>A p.F199L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV99686697; called by muse, mutect2, varscan2
- MMP9 | c.1636A>T p.R546W | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV100812370; called by muse, mutect2, varscan2
- MMRN1 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 40/569 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV99306724; called by muse, mutect2
- MMRN1 | c.2146C>A p.R716S | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as COSV99306726; called by muse, mutect2
- MMRN2 | c.343A>T p.T115S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.031); catalogued as COSV100922521; called by muse, mutect2
- MOG | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100972971; called by muse, mutect2, varscan2
- MOG | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs763930741, COSV100972973; called by muse, mutect2, varscan2
- MPL | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100991414; called by muse, mutect2
- MPO | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.367); catalogued as COSV99832403; called by muse, mutect2, varscan2
- MPPED2 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100813091; called by muse, mutect2, varscan2
- MRAP2 | c.592del p.Q198Rfs*14 | Frame Shift Del (DEL) | VAF 25/183 reads (14%) | catalogued as COSV57633991; called by mutect2, pindel, varscan2
- MRC1 | c.4235A>C p.K1412T | Missense Mutation (SNP) | VAF 85/779 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1031747304; called by muse, mutect2, varscan2
- MROH2B | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV68187333; called by muse, mutect2, varscan2
- MRPL14 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 63/654 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100921030; called by muse, mutect2
- MRPS5 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as rs372157685, COSV99720725; called by muse, mutect2, varscan2
- MSGN1 | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99808695; called by muse, mutect2, varscan2
- MSRB2 | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV100919696; called by muse, mutect2, varscan2
- MST1 | c.311C>A p.T104K | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as rs370891487; called by muse, mutect2, varscan2
- MTHFD1L | c.1498G>T p.A500S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100944940; called by muse, mutect2, varscan2
- MUC16 | c.37800G>C p.L12600F | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.84); catalogued as rs1344850658, COSV101198789; called by muse, varscan2
- MUC16 | c.30569C>A p.P10190H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.957); catalogued as COSV101198790; called by muse, mutect2, varscan2
- MUC17 | c.1166G>C p.S389T | Missense Mutation (SNP) | VAF 69/601 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100072241; called by muse, mutect2, varscan2
- MUC7 | c.380C>G p.P127R | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV100512217; called by muse, mutect2, varscan2
- MUC7 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as COSV100512218; called by muse, mutect2, varscan2
- MUSK | c.2339C>T p.T780I | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754976866, COSV99503824; ClinVar: uncertain significance; called by muse, mutect2
- MXRA5 | c.8021C>A p.P2674H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476119; called by muse, mutect2, varscan2
- MXRA5 | c.4925G>T p.W1642L | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54242064, COSV99476122; called by muse, mutect2, varscan2
- MYBBP1A | c.3590C>T p.P1197L | Missense Mutation (SNP) | VAF 97/311 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs776740818, COSV99625573; called by muse, mutect2, varscan2
- MYCBP2 | c.9867G>T p.M3289I (on ENST00000357337; = p.M3327I on NM_015057.5) | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV100629499; called by muse, mutect2, varscan2
- MYH1 | c.1998G>T p.L666F | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99875235; called by muse, mutect2, varscan2
- MYH1 | c.1947G>C p.Q649H | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1268365207, COSV99875237; called by muse, mutect2
- MYH13 | c.5374C>A p.Q1792K | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV99352856; called by muse, mutect2, varscan2
- MYH7 | c.4048G>T p.E1350* | Nonsense Mutation (SNP) | VAF 22/171 reads (13%) | catalogued as CM138713, COSV100805827, COSV100806924, COSV62516539; called by muse, mutect2, varscan2
- MYLK | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 45/361 reads (12%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.601); catalogued as COSV100658656; called by muse, mutect2, varscan2
- MYO1A | c.1952G>T p.G651V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100270658, COSV100270725; called by muse, mutect2, varscan2
- MYO1E | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.506); catalogued as COSV55683765, COSV99894840; called by muse, mutect2, varscan2
- MYO1E | c.1617-1G>T p.X539_splice | Splice Site (SNP) | VAF 14/143 reads (10%) | catalogued as COSV99894843; called by muse, mutect2, varscan2
- MYO7B | c.4649G>T p.R1550M | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101267968; called by muse, mutect2, varscan2
- MYOC | c.197A>T p.Q66L | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as COSV99231363; called by muse, mutect2
- MYT1L | c.1052C>A p.P351Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV67726585, COSV67733928; called by muse, mutect2, varscan2
- MYT1L | c.784G>C p.V262L | Missense Mutation (SNP) | VAF 29/294 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101219416; called by muse, mutect2, varscan2
- NAA11 | c.343A>T p.N115Y | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99727239; called by muse, mutect2, varscan2
- NAALAD2 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 27/392 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100428165; called by muse, mutect2
- NACA | c.568G>C p.V190L | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV100771155; called by muse, mutect2
- NALCN | c.3511G>T p.D1171Y | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51952860, COSV99213576; called by muse, mutect2
- NALCN | c.2295-1G>T p.X765_splice | Splice Site (SNP) | VAF 44/177 reads (25%) | catalogued as COSV99213578; called by muse, mutect2, varscan2
- NALCN | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99213580; called by muse, mutect2
- NAP1L3 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as COSV100220234; called by muse, mutect2, varscan2
- NAT2 | c.63G>C p.L21F | Missense Mutation (SNP) | VAF 97/271 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54061149, COSV99673984; called by muse, mutect2, varscan2
- NAV3 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.43); catalogued as COSV99888158; called by muse, mutect2, varscan2
- NAV3 | c.2756G>T p.R919M | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV99888160; called by muse, mutect2, varscan2
- NAV3 | c.2810C>A p.T937N | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.086); catalogued as COSV99888164; called by muse, mutect2
- NAV3 | c.4723C>G p.R1575G | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57063340, COSV57118643, COSV99888175; called by mutect2, varscan2
- NBR1 | c.1281G>T p.K427N | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100357742; called by muse, mutect2, varscan2
- NCAPG2 | c.538-1G>A p.X180_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99316669; called by muse, mutect2, varscan2
- NCDN | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs138793608, COSV100357028; called by muse, mutect2, varscan2
- NCOA6 | c.2634G>T p.K878N | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100749936; called by muse, mutect2, varscan2
- NCOA7 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57655532, COSV99996654; called by muse, mutect2, varscan2
- NCOR1 | c.3028G>T p.A1010S | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV99248322; called by muse, mutect2, varscan2
- NDUFA12 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV100580828; called by muse, mutect2
- NDUFB9 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs774728394, COSV99412712; called by muse, mutect2, varscan2
- NDUFS1 | c.987+1G>T p.X329_splice | Splice Site (SNP) | VAF 15/119 reads (13%) | catalogued as COSV99260587; called by muse, mutect2, varscan2
- NDUFS1 | c.987G>T p.M329I | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV51912720, COSV99260594; called by muse, mutect2, varscan2
- NEFH | c.2717C>A p.P906Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as COSV100151359; called by muse, mutect2
- NEU4 | c.950C>T p.P317L (on ENST00000391969 / NM_001167602.3; = p.P329L on NM_080741.4) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1055745798, COSV100371885; called by muse, mutect2, varscan2
- NFKB2 | c.1711G>T p.G571C | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV99192259; called by muse, mutect2, varscan2
- NHS | c.2466G>T p.R822S | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV101196458; called by muse, mutect2, varscan2
- NHS | c.2818A>G p.R940G | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV101196459; called by muse, mutect2, varscan2
- NHSL2 | c.1383C>A p.D461E (on ENST00000510661; = p.D827E on NM_001013627.2) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.586); catalogued as COSV101029940; called by muse, mutect2
- NLGN1 | c.1649G>C p.G550A | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848911; called by muse, mutect2, varscan2
- NLRP10 | c.795G>T p.R265S | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.348); catalogued as rs200543557, COSV100149543; called by muse, mutect2, varscan2
- NLRP13 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100738089; called by muse, mutect2, varscan2
- NLRP14 | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100204696; called by muse, mutect2, varscan2
- NLRP3 | c.1288C>A p.L430I | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100275540, COSV100276786; called by muse, mutect2, varscan2
- NLRP3 | c.2425G>C p.G809R | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as CM1314721, COSV100275543, COSV60222362; called by muse, mutect2, varscan2
- NLRP4 | c.546C>A p.F182L | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100015830, COSV56714148; called by muse, mutect2, varscan2
- NLRP8 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.071); catalogued as rs1445549378, COSV99404892; called by muse, mutect2, varscan2
1,074 further variants in this file (663 protein-altering or splice-affecting, 365 silent, 46 other) are not listed here.
